Somatic mutation profile of tumor specimen MBCProject_0573_T2_WES (aliquot MBCProject_0573_T2_WES_1) from CMI case MBCProject_0573, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.3 years (13,241 days).
Specimen MBCProject_0573_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cfa4f5d-03e0-4e27-8831-54eeb62cfe70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0573_SALIVA (Saliva), aliquot MBCProject_0573_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56db0082-4d1a-4e60-bcca-a34d2a4f3ee4

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC4F | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs782562166; called by muse, mutect2, varscan2
- CRACDL | c.893C>G p.P298R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs775039721; called by muse, mutect2
- OR2D2 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | catalogued as COSV55057924; called by muse, mutect2
- SLC9B1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs1478737822; called by muse, mutect2
- TRPC3 | c.589C>T p.H197Y (on ENST00000379645 / NM_001366479.2; = p.H124Y on NM_003305.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375570247; called by mutect2, varscan2
- TTN | c.49778C>T p.P16593L (on ENST00000591111; = p.P9169L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | PolyPhen benign (0.003); catalogued as rs1261823166; called by muse, mutect2
- TTN | c.49546A>G p.K16516E (on ENST00000591111; = p.K9092E on NM_003319.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.028); catalogued as rs886055263; ClinVar: uncertain significance; called by muse, mutect2
- ALOX15 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by mutect2, varscan2
- APOB | c.3305C>A p.T1102N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ATP1B3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2
- BLID | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 23/430 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); called by muse, mutect2
- COL9A1 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); called by muse, mutect2
- DAAM2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH11 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DUSP9 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DVL1 | c.769+1G>T p.X257_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- ELOVL1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- HJURP | c.1409del p.G470Vfs*11 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- KAT6B | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 30/337 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2
- KLHL10 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LMTK3 | c.2386G>C p.E796Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LUC7L3 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2
- NME1-NME2 | c.864C>G p.D288E (on ENST00000555572; = p.D263E on NM_001018136.3) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- NXF1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.828); called by muse, mutect2
- SALL4 | c.1570G>T p.V524L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAF4 | c.3146G>C p.R1049T | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2
- SLC7A7 | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- SPINK1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWC2 | c.152_195del p.A51Gfs*23 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel
- WDR72 | c.3004_3048del p.K1002_M1016del | In Frame Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, pindel
- ZNFX1 | c.3663G>C p.L1221F | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA3 | c.3156T>C p.T1052= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- APOB | c.3306T>A p.T1102= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8034G>A p.R2678= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- GALNTL6 | c.432C>T p.I144= | Silent (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- KRTAP10-11 | c.375G>A p.S125= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs192041610; called by muse, mutect2, varscan2
- POGZ | c.3913C>T p.L1305= | Silent (SNP) | VAF 19/265 reads (7%) | called by muse, mutect2
- TBC1D13 | c.441C>G p.L147= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV56353823; called by muse, mutect2
- TF | c.978C>A p.P326= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs761104997, COSV53917487, COSV99395595; called by muse, mutect2, varscan2
- TFG | c.402T>C p.N134= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- XIAP | c.384C>G p.A128= | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- ACBD6 | c.*1646C>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- PWWP2B | c.*47C>A | 3'UTR (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- UROD | c.276+30A>C | Intron (SNP) | VAF 42/574 reads (7%) | called by muse, mutect2
